Somatic mutation profile of tumor specimen TCGA-2G-AAGJ-01A (aliquot TCGA-2G-AAGJ-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGJ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 28.3 years (10,348 days).
Specimen TCGA-2G-AAGJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6570f64-50d2-42cd-ab42-3479be051d38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGJ-10A (Blood Derived Normal), aliquot TCGA-2G-AAGJ-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad6716b1-3e1c-499c-a809-e9532341ff98

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Splice Site 2, Frame Shift Del 2, Intron 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACMSD | c.849+1G>T p.X283_splice | Splice Site (SNP) | VAF 26/136 reads (19%) | catalogued as COSV51609660; called by muse, mutect2, varscan2
- C4orf51 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV101440046; called by muse, mutect2
- GOLGA6L1 | c.1559G>A p.R520K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.14); catalogued as rs1357472957; called by muse, mutect2, varscan2
- SI | c.4964G>T p.R1655L | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.318); catalogued as rs752540924, COSV100017187; called by muse, mutect2, varscan2
- WDR45B | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs139641537; called by muse, mutect2, varscan2
- ADGRG5 | c.686T>C p.F229S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPI | c.300+1G>A p.X100_splice | Splice Site (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- B3GALT6 | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BRWD3 | c.2752C>A p.P918T | Missense Mutation (SNP) | VAF 125/453 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CYP17A1 | c.733A>T p.K245* | Nonsense Mutation (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- DLC1 | c.396del p.Q133Rfs*8 | Frame Shift Del (DEL) | VAF 17/122 reads (14%) | called by mutect2, pindel, varscan2
- FRG2 | c.558_561del p.Y187Kfs*3 | Frame Shift Del (DEL) | VAF 37/159 reads (23%) | called by mutect2, pindel, varscan2
- NMNAT2 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- OR5J2 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, varscan2
- PRR32 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TELO2 | c.1587G>T p.E529D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ZBTB37 | c.584G>C p.S195T | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ATP2B1 | c.1248T>C p.F416= | Silent (SNP) | VAF 29/234 reads (12%) | called by muse, mutect2, varscan2
- DVL1 | c.1371C>T p.H457= (on ENST00000378888 / NM_001330311.2; = p.H432= on NM_004421.3) | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs151161721; called by muse, mutect2, varscan2
- IL4I1 | c.198C>T p.G66= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs138779872; called by muse, mutect2, varscan2
- PALB2 | c.3432C>T p.L1144= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs748363227; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- TEPSIN | c.984G>A p.E328= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1410A>T p.I470= | Silent (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+10053_25+10054del | Intron (DEL) | VAF 18/112 reads (16%) | called by pindel, varscan2
- CNTNAP3P2 | n.180C>A | RNA (SNP) | VAF 33/363 reads (9%) | called by muse, mutect2, varscan2
- MAGED1 | c.45+308C>A | Intron (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
